Gene-level copy-number profile of tumor specimen ALCH-B4ZK-TTP1-A from ALCHEMIST case ALCH-B4ZK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,316 days).
Specimen ALCH-B4ZK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 041873df-1e76-4b5c-b506-38aba9c900d3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4ZK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/b2e3741e-ef1e-4391-877f-5c3928780b80

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 2,058; copy number 2: 49,905; copy number 3: 6,086; copy number 4: 190; copy number 5: 4; copy number 6: 38; copy number 7: 96; copy number 9: 10; copy number 10: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,466,699–212,472,905, 1 gene: LINC02771.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–2): AP001271.2.
- chr11:70,646,165–70,647,562, 1 gene (within-gene range 0–2): SHANK2-AS2.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–2): AC004882.1, AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 153 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:524,109–784,729, 7 genes, copy number 7 (within-gene range 2–7): AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B.
- chr5:850,291–3,181,487, 53 genes, copy number 6–7 (within-gene range 2–7): BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377.
- chr7:77,043,721–77,198,626, 2 genes, copy number 9 (within-gene range 3–9): AC007000.3, SPDYE18.
- chr7:77,083,787–77,329,533, 5 genes, copy number 9 (within-gene range 3–9): FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1.
- chr7:79,452,877–79,654,227, 3 genes, copy number 5–9 (within-gene range 3–9): MAGI2-AS3, NUP35P2, RNA5SP234.
- chr7:79,912,104–79,912,208, 1 gene, copy number 5: RNU6-849P.
- chr7:144,849,755–145,584,817, 6 genes, copy number 6–9: RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2.
- chr14:35,819,224–36,656,163, 25 genes, copy number 6 (within-gene range 2–6): AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257.
- chr16:23,061,406–23,149,270, 1 gene, copy number 5 (within-gene range 3–5): USP31.
- chr20:63,587,602–64,327,972, 50 genes, copy number 7–10: GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 2,058. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
